Somatic mutation profile of tumor specimen MMRF_2413_1_BM_CD138pos (aliquot MMRF_2413_1_BM_CD138pos_T1_KHS5U_L11242) from MMRF case MMRF_2413, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.4 years (22,428 days).
Specimen MMRF_2413_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bf7ec9b-4673-4890-b2f1-ffba75ac141c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2413_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2413_1_PB_WBC_C3_KHS5U_L11241; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7998bd4-ead3-4834-bc7e-410812adfcdd

The open-access MAF lists 123 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 27, Intron 18, Silent 16, 5'UTR 4, Nonsense Mutation 3, 5'Flank 3, Splice Site 2, RNA 2, In Frame Del 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.352); catalogued as rs576584879; called by muse, mutect2, varscan2
- ARSJ | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1482378450; called by muse, mutect2, varscan2
- CEP57 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs562909477; called by muse, varscan2
- CPA3 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 112/493 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141324442; called by muse, mutect2, varscan2
- HDLBP | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as rs1200458864, COSV100190315; called by muse, mutect2, varscan2
- HMCN1 | c.6331C>T p.Q2111* | Nonsense Mutation (SNP) | VAF 27/362 reads (7%) | catalogued as rs765450462; called by muse, mutect2
- IGHV3-7 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs572360030; called by muse, varscan2
- IGLV3-1 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561948127; called by muse, mutect2, varscan2
- ITPR1 | c.6703G>T p.E2235* (on ENST00000354582; = p.E2180* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 84/313 reads (27%) | catalogued as COSV56987052; called by muse, mutect2
- LPP | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.169); catalogued as COSV100446295; called by muse, mutect2, varscan2
- LRRN1 | c.2015C>A p.T672N | Missense Mutation (SNP) | VAF 119/461 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100076349; called by muse, mutect2, varscan2
- MAB21L3 | c.903G>C p.W301C | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201089101; called by muse, mutect2, varscan2
- MELK | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1220796077, COSV53197513; called by muse, mutect2, varscan2
- MTERF4 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1382860046; called by muse, mutect2, varscan2
- NID1 | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); catalogued as rs1339306331; called by muse, mutect2, varscan2
- PPL | c.778A>T p.N260Y | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs753326470; called by muse, mutect2
- RGS3 | c.2671G>C p.G891R (on ENST00000350696 / NM_001282923.2; = p.G610R on NM_130795.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs774689229; called by muse, mutect2, varscan2
- SPHKAP | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1461980426, COSV60878807; called by muse, mutect2
- SYK | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs755100350, COSV65330903; called by muse, mutect2, varscan2
- TMEM63C | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs769683393; called by muse, mutect2, varscan2
- TSHZ2 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs1484078042, COSV61589279; called by muse, mutect2, varscan2
- ZFHX4 | c.1000A>T p.S334C | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV104378957; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.538_541del p.S180Vfs*10 | Frame Shift Del (DEL) | VAF 70/254 reads (28%) | called by pindel, varscan2
- ASXL3 | c.354A>T p.G118= | Splice Region (SNP) | VAF 37/159 reads (23%) | called by muse, mutect2, varscan2
- ATAD2B | c.2466A>C p.E822D | Missense Mutation (SNP) | VAF 75/128 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CEP57 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CFAP70 | c.787C>G p.P263A | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.044); called by muse, mutect2
- COL12A1 | c.3067G>T p.V1023F | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- DPF1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSG4 | c.2036A>G p.Q679R | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EDEM2 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FAM186A | c.2965C>T p.Q989* | Nonsense Mutation (SNP) | VAF 93/286 reads (33%) | called by muse, mutect2, varscan2
- GPRIN3 | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- HAS3 | c.1532C>G p.A511G | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- HMCN1 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INHBC | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- IRGQ | c.996C>A p.D332E | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ITIH6 | c.3730+1G>T p.X1244_splice | Splice Site (SNP) | VAF 24/34 reads (71%) | called by muse, mutect2, varscan2
- LAMP3 | c.759+2T>G p.X253_splice | Splice Site (SNP) | VAF 56/235 reads (24%) | called by muse, mutect2, varscan2
- MAPT | c.2362T>A p.S788T (on ENST00000262410 / NM_001377265.1; = p.S396T on NM_005910.5) | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL1 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PABPC4L | c.171C>A p.N57K | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PACSIN2 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- SALL2 | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SH2D3C | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC25A39 | c.805G>A p.A269T (on ENST00000377095 / NM_001143780.3; = p.A261T on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC25A39 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SLC25A39 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC7A6OS | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPINDOC | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TOR3A | c.34_51del p.F12_L17del | In Frame Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel
- TOX | c.1108T>C p.Y370H | Missense Mutation (SNP) | VAF 121/339 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ABCA3 | c.4989C>T p.F1663= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as rs1273572317; called by muse, mutect2, varscan2
- CES4A | c.1287C>A p.A429= | Silent (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- CTSO | c.606T>C p.G202= | Silent (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- FZD2 | c.447C>A p.I149= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs376053430; called by muse, mutect2, varscan2
- GPATCH8 | c.3441G>A p.L1147= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV59198409; called by muse, mutect2
- H2BC18 | c.156C>T p.D52= | Silent (SNP) | VAF 51/257 reads (20%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.252A>G p.P84= | Silent (SNP) | VAF 72/226 reads (32%) | called by muse, mutect2, varscan2
- MYH8 | c.2028C>T p.I676= | Silent (SNP) | VAF 52/94 reads (55%) | called by muse, mutect2, varscan2
- OR4A5 | c.525T>C p.S175= | Silent (SNP) | VAF 45/136 reads (33%) | called by muse, mutect2, varscan2
- PCDH15 | c.4302G>A p.A1434= | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as rs368622542; called by muse, mutect2, varscan2
- PCDHA8 | c.390G>A p.P130= | Silent (SNP) | VAF 46/170 reads (27%) | catalogued as rs1385576183, COSV65335649; called by muse, mutect2, varscan2
- RIMBP2 | c.408C>A p.T136= | Silent (SNP) | VAF 91/263 reads (35%) | catalogued as rs374575815; called by muse, mutect2, varscan2
- SLC25A39 | c.918G>A p.L306= (on ENST00000377095 / NM_001143780.3; = p.L298= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- SP5 | c.408G>A p.A136= | Silent (SNP) | VAF 68/194 reads (35%) | catalogued as rs770907320; called by muse, mutect2, varscan2
- TTBK1 | c.3312G>A p.R1104= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TTN | c.86925A>G p.V28975= (on ENST00000591111; = p.V21551= on NM_003319.4) | Silent (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
- ACTB | c.-27-117T>A | Intron (SNP) | VAF 70/206 reads (34%) | called by muse, mutect2, varscan2
- ADAR | c.*1027C>T | 3'UTR (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- APOF | c.-110C>T | 5'UTR (SNP) | VAF 64/203 reads (32%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.*1056A>G | 3'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.879+9999C>G | Intron (SNP) | VAF 38/138 reads (28%) | called by muse, mutect2, varscan2
- CALHM5 | c.*7672G>A | 3'UTR (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- CEP57 | c.45+3548C>T | Intron (SNP) | VAF 40/121 reads (33%) | catalogued as rs77498708; called by muse, varscan2
- CERS1 | c.1010+83C>A | Intron (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- CNGB3 | c.*1573C>T | 3'UTR (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- CNTN3 | c.*1236A>G | 3'UTR (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- COA6 | c.*132A>C | 3'UTR (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- DCP1B | c.319+49A>G | Intron (SNP) | VAF 60/175 reads (34%) | called by muse, mutect2, varscan2
- DCTN4 | c.*1964A>G | 3'UTR (SNP) | VAF 54/160 reads (34%) | called by muse, mutect2, varscan2
- DICER1 | c.*1899T>A | 3'UTR (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- DLG4 | c.*712G>A | 3'UTR (SNP) | VAF 10/13 reads (77%) | catalogued as rs1297351130; called by muse, mutect2, varscan2
- EEF1B2 | c.203+208C>T | Intron (SNP) | VAF 119/370 reads (32%) | called by muse, mutect2, varscan2
- ERBIN | c.*3874C>T | 3'UTR (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- FUT4 | c.*597G>C | 3'UTR (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- GNG2 | c.*1666T>A | 3'UTR (SNP) | VAF 20/61 reads (33%) | called by mutect2, varscan2
- HGF | c.482+371A>G | Intron (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- HNF4G | c.-23-3734A>T | Intron (SNP) | VAF 60/137 reads (44%) | called by muse, mutect2, varscan2
- IGHV3-7 | c.-61T>G | 5'UTR (SNP) | VAF 30/108 reads (28%) | called by muse, varscan2
- INPP4B | chr4:142026063 del A | 3'Flank (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- IQCK | c.376+75G>A | Intron (SNP) | VAF 10/37 reads (27%) | catalogued as rs561536239; called by muse, mutect2, varscan2
- KRT20 | c.*343T>A | 3'UTR (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
- LINC00305 | n.1148T>C | RNA (SNP) | VAF 47/186 reads (25%) | called by muse, mutect2, varscan2
- LINC01553 | n.198G>A | RNA (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- LTB | c.163-152A>C | Intron (SNP) | VAF 185/312 reads (59%) | called by muse, mutect2, varscan2
- MME | c.*2057A>G | 3'UTR (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- MYBL1 | c.-194G>A | 5'UTR (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- PDE10A | c.*1322T>G | 3'UTR (SNP) | VAF 66/99 reads (67%) | called by muse, mutect2, varscan2
- PDE5A | c.*1074T>C | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- PDE6B | c.927+181G>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- POFUT2 | c.*792_*816del | 3'UTR (DEL) | VAF 18/41 reads (44%) | catalogued as rs565644510; called by mutect2, varscan2*
- PSMD5 | chr9:120843236 C>T | 5'Flank (SNP) | VAF 57/249 reads (23%) | catalogued as rs1157924584; called by muse, mutect2, varscan2
- PTPRT | c.*3276G>T | 3'UTR (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- RGSL1 | c.463+20T>C | Intron (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- RIPOR3 | c.*502C>G | 3'UTR (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.950+49C>T | Intron (SNP) | VAF 12/20 reads (60%) | catalogued as COSV63530438; called by muse, mutect2, varscan2
- SHKBP1 | c.87-102G>C | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as rs1161666651; called by muse, mutect2
- SKOR1 | c.*695T>G | 3'UTR (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- SLC25A39 | c.*361G>A | 3'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, varscan2
- SLC25A39 | c.*276G>A | 3'UTR (SNP) | VAF 25/86 reads (29%) | called by muse, varscan2
- SNRK | c.*369_*380del | 3'UTR (DEL) | VAF 33/183 reads (18%) | called by mutect2, pindel, varscan2
- SNX1 | c.1365+98G>A | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- SNX1 | c.*856A>T | 3'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- SNX16 | c.*538A>T | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- SPIRE1 | chr18:12658251 A>C | 5'Flank (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2
- SPOPL | c.*2117T>G | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- TAF7 | c.-624C>T | 5'UTR (SNP) | VAF 153/277 reads (55%) | called by muse, mutect2, varscan2
- TAMM41 | c.318+124G>A | Intron (SNP) | VAF 52/88 reads (59%) | called by muse, mutect2, varscan2
- TBC1D15 | chr12:71839709 T>C | 5'Flank (SNP) | VAF 123/318 reads (39%) | called by muse, mutect2, varscan2
- TMBIM6 | c.-31+651A>G | Intron (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- USE1 | c.103-61dup | Intron (INS) | VAF 8/30 reads (27%) | catalogued as rs1192605865; called by mutect2, varscan2
- ZBBX | c.*287C>A | 3'UTR (SNP) | VAF 18/131 reads (14%) | called by mutect2, varscan2
